Somatic mutation profile of tumor specimen TCGA-B3-3925-01A (aliquot TCGA-B3-3925-01A-01D-1252-08) from TCGA case TCGA-B3-3925, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 52.6 years (19,224 days).
Specimen TCGA-B3-3925-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d964636-97ba-4ca8-8f0c-af96df98af7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B3-3925-10A (Blood Derived Normal), aliquot TCGA-B3-3925-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2c31cde-ad1f-4544-ad5f-cdc12bed26c8

The open-access MAF lists 77 somatic variants for this specimen: 55 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 2, 3'Flank 2, 5'UTR 1, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL592490.1 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69427449; called by muse, mutect2
- AMY2B | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs143243690; called by muse, mutect2, varscan2
- ASB15 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV51923926; called by muse, mutect2, varscan2
- ATP6V1A | c.479C>G p.S160W | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs760446373; called by muse, mutect2, varscan2
- DDR1 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 217/647 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764833803; called by muse, mutect2, varscan2
- GIPR | c.1167C>G p.S389R | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs529800464; called by muse, mutect2, varscan2
- GNAZ | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 97/393 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV50737110; called by muse, mutect2, varscan2
- IGHV3-30 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 79/578 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.308); catalogued as rs752676641; called by muse, varscan2
- MYH7 | c.4459G>A p.A1487T | Missense Mutation (SNP) | VAF 153/477 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs766909770, COSV62524750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAF1 | c.1171A>T p.R391W | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368807126; called by muse, mutect2, varscan2
- SIGLEC9 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV99142885; called by muse, mutect2, varscan2
- TOP2B | c.4408G>T p.D1470Y (on ENST00000264331 / NM_001330700.2; = p.D1465Y on NM_001068.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs1253027961, COSV51971629; called by muse, mutect2, varscan2
- ZFP41 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs761878631, COSV58087715; called by muse, mutect2, varscan2
- ZZEF1 | c.5903G>A p.G1968E | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as rs762767015; called by muse, mutect2
- ABCE1 | c.1144+1G>A p.X382_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 92/288 reads (32%) | called by muse, mutect2, varscan2
- ANAPC5 | c.2093_2096del p.K698Tfs*53 | Frame Shift Del (DEL) | VAF 170/401 reads (42%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.5165del p.N1722Tfs*5 (on ENST00000310343 / NM_001378025.1; = p.N1373Tfs*5 on NM_014715.4) | Frame Shift Del (DEL) | VAF 88/283 reads (31%) | called by mutect2, pindel, varscan2
- BMP1 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CALML4 | c.115A>C p.S39R | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC63 | c.861G>C p.K287N | Missense Mutation (SNP) | VAF 268/530 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- CCDC9B | c.74del p.F25Sfs*33 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- CD40 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEPDC5 | c.823A>T p.K275* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- FGF21 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 174/438 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GIGYF2 | c.2370+2T>A p.X790_splice | Splice Site (SNP) | VAF 26/90 reads (29%) | called by muse, varscan2
- GLDN | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GYS2 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- KHDC4 | c.398G>C p.S133T | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- LCOR | c.1107_1109del p.L370del | In Frame Del (DEL) | VAF 31/72 reads (43%) | called by mutect2, pindel, varscan2
- LRIG2 | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 188/523 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM | c.5262T>G p.D1754E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- OGG1 | c.820_821insAA p.I274Kfs*133 | Frame Shift Ins (INS) | VAF 55/172 reads (32%) | called by mutect2, varscan2
- OGG1 | c.821delinsAAA p.I274Kfs*133 | Frame Shift Ins (INS) | VAF 47/159 reads (30%) | called by mutect2*, pindel, varscan2*
- PLCB2 | c.580A>T p.K194* | Nonsense Mutation (SNP) | VAF 46/141 reads (33%) | called by muse, mutect2, varscan2
- POSTN | c.1511A>C p.K504T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PYROXD2 | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- QRICH2 | c.3449A>T p.Q1150L | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RAB27B | c.346_349del p.Q116Cfs*12 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- RAET1L | c.630A>T p.G210= | Splice Region (SNP) | VAF 100/332 reads (30%) | called by muse, mutect2, varscan2
- RFX2 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 167/442 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLX4 | c.2466G>C p.M822I | Missense Mutation (SNP) | VAF 150/469 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SNTB1 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.2747G>A p.W916* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- SRCAP | c.3043C>A p.P1015T | Missense Mutation (SNP) | VAF 119/347 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- STON1 | c.1184A>G p.E395G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBCD | c.3109G>C p.E1037Q | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- TIGD2 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- TMCC2 | c.1216G>T p.V406F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TSFM | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 120/511 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USF1 | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13C | c.6141G>C p.K2047N (on ENST00000644861 / NM_020821.3; = p.K2004N on NM_017684.5) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- VWC2L | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- ZAN | c.6962G>T p.S2321I | Missense Mutation (SNP) | VAF 281/538 reads (52%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZNFX1 | c.586A>G p.S196G | Missense Mutation (SNP) | VAF 153/285 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CABIN1 | c.795T>A p.I265= | Silent (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- CERS2 | c.225G>A p.R75= | Silent (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- COL17A1 | c.4095T>C p.A1365= | Silent (SNP) | VAF 55/210 reads (26%) | called by muse, mutect2, varscan2
- CTPS2 | c.1242T>G p.L414= | Silent (SNP) | VAF 112/150 reads (75%) | called by muse, mutect2, varscan2
- FBXO11 | c.1440A>C p.A480= (on ENST00000403359 / NM_001190274.2; = p.A396= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV57026506; called by muse, mutect2, varscan2
- HDHD2 | c.90A>G p.E30= | Silent (SNP) | VAF 56/170 reads (33%) | called by muse, mutect2, varscan2
- IMMT | c.2253A>C p.G751= | Silent (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- MUC17 | c.12657G>A p.T4219= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as rs200175178; called by muse, mutect2, varscan2
- MUC5AC | c.15075C>T p.G5025= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs748170322; called by muse, mutect2, varscan2
- MXRA5 | c.5007T>C p.S1669= | Silent (SNP) | VAF 146/205 reads (71%) | called by muse, mutect2, varscan2
- MYO5B | c.1305G>A p.G435= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as rs746993416; called by muse, mutect2, varscan2
- MYO9A | c.3373A>C p.R1125= | Silent (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- PAOX | c.588C>T p.G196= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- PCDH18 | c.2388C>T p.H796= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- PSMC4 | c.1065T>C p.S355= | Silent (SNP) | VAF 187/486 reads (38%) | called by muse, mutect2, varscan2
- PTPRE | c.570C>A p.I190= | Silent (SNP) | VAF 63/180 reads (35%) | catalogued as rs991804759; called by muse, mutect2, varscan2
- SMG1 | c.8583C>T p.F2861= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- SOX10 | c.555G>A p.Q185= | Silent (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1418G>A | RNA (SNP) | VAF 11/17 reads (65%) | catalogued as rs1330339765; called by muse, mutect2, varscan2
- POM121C | chr7:75416562 A>G | 3'Flank (SNP) | VAF 121/276 reads (44%) | called by muse, mutect2, varscan2
- PREP | c.-48G>C | 5'UTR (SNP) | VAF 40/106 reads (38%) | catalogued as rs774243006, COSV64872553; called by muse, mutect2, varscan2
- RUFY3 | chr4:70793847 A>G | 3'Flank (SNP) | VAF 29/84 reads (35%) | catalogued as COSV56917737; called by muse, mutect2, varscan2
